Surgical pathology report (de-identified scan), TCGA case TCGA-18-3419, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-3419-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lymph-Node: ST10L TB Angle
2. Lymph node: Subcarinal st7
3. LUNGS: Left lung. Bronchial resection margin
4. Lymph node: Inferior pulmonary ligament st9

DIAGNOSIS

- 1., 2. ST10L TB angle, Subcarinal ST7, lymph node dissection:
- Negative for malignancy, lymph node. (x2)
3. Left lung pneumonectomy:
- Poorly differentiated squamous cell carcinoma, central, arising and obstructing lower lobe bronchus with extension to involve the main bronchus bifurcation.
- Tumor 5.7 cm in greatest diameter, 2.3 cm from bronchial resection margin. (pT2)
- Bronchial resection margin negative for tumor
- Tumor has invaded the pulmonary artery, vascular resection margin negative for tumor.
- Interlobar node extensively infiltrated by tumor.
- Eight lower lobe lobar and 2 upper lobe lobar nodes negative for tumor. (pN0)
- Blood and lymphatic vessels invasion noted.
- Lower lobe bronchial mucous impaction with obstructive pneumonia.
- Centroacinar emphysema, marked.
4. Inferior pulmonary ligament ST9 lymph node:
- Negative for malignancy, adipose tissue only.

SYNOPTIC DATA

Specimen Type:	Pneumonectomy
Laterality:	Left

[page 2 of 4]
Tumor Site: Other: (LLL bronchus extending to
lobar bifurcation)
Tumor Size: Greatest dimension: 5.7 cm
Additional dimensions: 5.0 x 4.0 cm
Histologic Type: Squamous cell carcinoma
Histologic Grade: G3: Poorly differentiated
Pathologic Staging (pTNM): pT2: Tumor with any of the following
features of size or extent: greater than 3 cm in greatest dimension;
involves main bronchus, 2 cm or more distal to the carina; invades the
visceral pleura; associated with atelectasis or obstructive pneumonitis
that extends to the hilar region but does not involve the entire lung
pN1: Metastasis in ipsilateral
peribronchial and/or ipsilateral hilar lymph nodes, including
intrapulmonary nodes involved by direct extension of the primary tumor
Lymph node stations
involved: 11L (Left interlobar)
pMX: Cannot be assessed
Margins: Margins uninvolved by invasive
carcinoma
Distance of invasive carcinoma from
closest margin: 2.3 mm
Margin: (Main bronchus)
Direct Extension of Tumor: Other (specify): pulmonary artery
Blood Vessel Invasion: Present
Lymphatic (Small Vessel) Invasion (L): Present
Additional Pathologic Findings: Severe centrilobular emphysema
Other: Obstructive pneumonia, lower
lobe

COMMENT

This is a centrally located tumor that extends from the lower lobe bronchus to the main bronchus bifurcation point. The interlobar node is extensively infiltrated by the tumor. At the hilum, the tumor has also invaded through the bronchial wall into adjacent fibroadipose tissue, with infiltration around a large nerve trunk noted. The lower lobe shows prominent mucous impaction and obstructive pneumonia.

[page 3 of 4]
CLINICAL HISTORY
CA. LUNG

GROSS DESCRIPTION

1. The specimen container is labeled with the patient's identification and as "Lymph Node: ST10L TB angle". It contains one piece of red-tan tissue measuring 1.0 x 0.4 x 0.3 cm. The specimen is submitted in toto for frozen section.

1- frozen section resubmitted.

2. The specimen container is labeled with the patient's identification and as "Lymph Node: Subcarinal ST7". It contains one piece of gray-brown tissue measuring 2.2 x 1.4 x 1.0 cm. Specimen submitted in toto in labeled "2A".

3. The specimen container is labeled with the patient's name and as "Lungs: Left lung. Bronchial resection margin qs" consists of a pneumonectomy specimen consisting of two lobes of lung tissue received fresh. This is examined at intraoperative consultation by frozen section performed on part of the specimen. The specimen measures 21.5 x 17.0 x 5.5 cm. The pleural surface is smooth and gray-tan in color with a small ill-defined area of puckering measuring about 3.5 cm. On sectioning, there is a tumor mass involving the left lower lobe lobar bronchus invading the lower lobe lung parenchyma and extends to the junction of bifurcation of the main bronchus. There is also a lower lobe lobar bronchus node that is grossly involved with an upper lobe bronchus interlobar node that is grossly involved by the tumor. The tumor mass appears to impinged on the vessel wall. This tumor mass measures 5.7 x 5.0 x 4.0 cm. This tumor is 2.3 cm from the main bronchus resection margin. Multiple hilar nodes are identified ranging in size from 0.5 x 0.3 x 0.2 cm to 4.5 x 2.5 x 2.5 cm. The remainder of the lung tissue is free from tumor but appears to be predominantly emphysematous with diffuse areas having mucous plugs and an area of consolidation with yellowish specks and firm on the medial basal segment. Representative sections are submitted as follows:

3A- bronchial resection margin frozen section resubmitted.

3B- vascular resection margin

3C- multiple nodes around lower lobe lobar bronchus

[page 4 of 4]
Four pieces of bronchial tumor, two pieces of tumor from hilar node, two pieces of bronchial mucosa and three pieces of lung tissue were taken for tissue banking.

QUICK SECTION

1A -Negative for carcinoma.
3A - Negative for carcinoma.

Source: NCI Genomic Data Commons file e99b7142-3faa-4366-8005-3a64a474d21b (TCGA-18-3419.BE697B2E-96C7-401C-935B-5046A939F6AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).